TARGET case TARGET-30-PARPGU — Neuroblastoma (TARGET-NBL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neuroepitheliomatous Neoplasms. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/1fcf56ca-6670-5330-a937-9951039b9188

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 3 years; Vital status: Dead; Days to death: 1,381 days (3.8 years).

Diagnoses (1)
1. Neuroblastoma, NOS: ICD-O-3 morphology code: 9500/3; ICD-10 code: C80.0; Tissue or organ of origin: Unknown primary site; Classification of tumor: primary; Age at diagnosis: 3.1 years (1,145 days); Year of diagnosis: 2007; Days to last follow up: 1,381 days (3.8 years); Cog neuroblastoma risk group: High Risk; Inpc grade: Undifferentiated or Poorly Differentiated; INSS stage: Stage 4.
   Pathology details: Necrosis percent: 10.
   Treatment given: Protocol identifier: ANBL00B1.

Follow-up (2 entries)
- Days to follow up: 686 days (1.9 years); Progression or recurrence anatomic site: Bone marrow; Days to first event: 686 days (1.9 years); First event: Relapse.
- Days to follow up: 1,381 days (3.8 years); Year of follow up: 2011.

Biospecimens (2 samples)
- Sample TARGET-30-PARPGU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-30-PARPGU-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_NBL_ClinicalData_Discovery_20230523.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 1381
- Histology: Unfavorable
- ICDO: C80.9
- Percent Tumor: 10-15
- Percent Tumor v/s Stroma: 10-15/90-85
